Gene-level copy-number profile of tumor specimen ALCH-AF3D-TTR1-A from ALCHEMIST case ALCH-AF3D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.4 years (23,143 days).
Specimen ALCH-AF3D-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cd127223-e543-4989-941e-30656dd641d5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF3D-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/6228eddb-e617-4e6b-9805-c1c16b0a40cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 3,839; copy number 2: 54,792; copy number 3: 216; copy number 4: 24; copy number 5: 6.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,978,943–44,031,467, 3 genes (within-gene range 0–2): B4GALT2, CCDC24, SLC6A9.
- chr4:1,009,936–1,028,972, 2 genes: FGFRL1, AC019103.1.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr11:63,985,853–64,001,811, 1 gene (within-gene range 0–2): OTUB1.
- chr12:31,105,105–31,106,830, 1 gene: AC008013.3.
- chr12:131,894,622–131,929,351, 3 genes (within-gene range 0–2): ULK1, AC131009.4, AC131009.1.
- chr14:104,137,150–104,180,894, 2 genes: AL359399.1, KIF26A.
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.
- chr19:19,512,418–19,546,659, 5 genes: TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2.
- chr21:44,217,014–44,244,993, 3 genes: ICOSLG, AP001059.2, AP001059.1.
- chr21:44,250,813–44,251,520, 1 gene (within-gene range 0–2): DNMT3L-AS1.
- chr22:18,846,811–18,861,049, 2 genes: AC008132.1, BCRP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:10,640,028–13,016,692, 3 genes, copy number 5: AF254982.1, IGHV1OR21-1, AP001464.1.
- chr22:18,906,028–18,947,732, 3 genes, copy number 5 (within-gene range 2–5): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 1,048. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
